Somatic mutation profile of tumor specimen 0DJPCS from CCDI case PBBXAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angiomatoid fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 11.3 years (4,137 days).
Specimen 0DJPCS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 840bf79f-baea-4a3f-891f-10c8e1a97297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJPCL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50210ba5-21f1-426e-a088-8727499e4025

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Intron 2, Missense Mutation 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV53961740, COSV99686289; called by muse, mutect2
- PCDHB14 | c.2087C>A p.S696* | Nonsense Mutation (SNP) | VAF 6/115 reads (5%) | catalogued as COSV53388518; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 28/755 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- C2orf16 | c.5535T>C p.S1845= | Silent (SNP) | VAF 18/478 reads (4%) | called by muse, mutect2
- RAPGEF1 | c.1536C>T p.P512= | Silent (SNP) | VAF 51/427 reads (12%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, varscan2
